Surgical pathology report (de-identified scan), TCGA case TCGA-WZ-A7V4, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site  International Genomics Consortium, specimen TCGA-WZ-A7V4-01A (Primary Tumor).

[page 1 of 2]
Results

Specimen Information

Collection Date and Time

Component Results

**SURGICAL PANEL:
SURGICAL PATHOLOGY REPORT**

Final Report

DIAGNOSIS

LEFT TESTIS, RADICAL ORCHIECTOMY:

1. Seminoma, classic type
2. Tumor is confined to the testis
3. Surgical margins are negative for tumor
4. Negative for lymphatic/vascular invasion by tumor
5. Intratubal germ cell neoplasia, unclassified
6. Epididymal cyst, benign
7. Please see testis cancer staging parameters below

*****2010 TESTIS CANCER STAGING PARAMETERS*****

Case number: Patient name:

Final TNM: pT1NXM0

2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Radical Orchiectomy

TUMOR LATERALITY

Left

TUMOR SIZE

3 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Seminoma, classic type

MARGINS

Spermatic cord: Uninvolved by tumor

MICROSCOPIC TUMOR EXTENSION

Tumor is limited to testis

LYMPHATIC/VASCULAR INVASION

Absent

PATHOLOGIC STAGING

EXTENT OF INVASION

pT1. (Tumor limited to the testis and epididymis without vascular/lymphatic invasion; tumor may invade into the tunica albuginea but not the tunica vaginalis)

REGIONAL LYMPH NODES

pNX. (Regional lymph nodes cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

SERUM TUMOR MARKERS

ICD-O-3

Seminoma NOS 9061/3

Site ^{CLL} Testes NOS C62.9

Path
① Testis NOS C62.9
9/10/4/13

[page 2 of 2]
[REDACTED]

SX. (Serum marker studies not available or performed [Although LDH, HCG, and AFP values may be available, the 'S' designation in AJCC staging specifically refers to post-orchietomy levels. These levels are currently not available])

PATHOLOGIC STAGE Summary

Final TNM: pT1NXM0

2010 stage: I

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

Left testicular mass

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Testicle, left

Received fresh labeled "left testicle" is a 6 x 5 x 2.5 cm testis and attached 11 cm in length and 1.8 cm in diameter spermatic cord. The tunical vaginalis is intact and inked blue. The testis is bisected revealing a 4.6 x 3.8 x 3 cm testis with a solid white, well circumscribed tumor mass, measuring 3 x 3 x 2.6 cm in the center of the specimen. There is a focus of normal-appearing testicle in which the seminiferous tubules separate easily. The proximal resection margin of the spermatic cord is submitted on chuck #1 and a representative portion of the tumor on chuck #2.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Seminoma, benign spermatic cord margin" is rendered by [REDACTED]

The tumor mass tethers focally to the tunica albuginea but does not extend through it. No secondary masses are noted. The epididymis is present, measures 7 x 1 x 1 cm and is notable for a possible cystic space, 0.5 cm. Note that tissue is taken for possible ancillary studies.

Representative sections are submitted in 13 cassettes labeled:

1. Frozen section, spermatic cord
2. Frozen section, tumor
3. Mid spermatic cord
- 4-7. Representative tumor and overlying vaginalis
8. Tumor, normal testis and albuginea
9. Tumor and normal parenchyma
10. Epididymis
11. Epididymis, cystic space, and vaginalis
12. Vaginalis overlying the tumor, no tumor
13. Base of spermatic cord

This case is accessioned in

Gross dictation by: [REDACTED]

MICROSCOPIC

Tumor is confined to the testis, but metaplastic adipose tissue is noted. Technical (tumor cell transfer) artifact of tumor is noted in the specimen slides.

Dictation by: [REDACTED]

Source: NCI Genomic Data Commons file 7b3720d6-3152-48cd-9b9b-d5a3fac6d018 (TCGA-WZ-A7V4.EB3A78EF-9BDD-4164-B37A-B10858DEA124.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).